Somatic mutation profile of cancer-model specimen HCM-BROD-0716-C43-85N (Adherent Cell Line, passage 8; aliquot HCM-BROD-0716-C43-85N-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0716-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.7 years (21,450 days).
Specimen HCM-BROD-0716-C43-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 8.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a62fc938-8375-4028-9e86-3450a7380137.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0716-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0716-C43-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85680397-6219-427e-a68c-66de24a814d8

The open-access MAF lists 759 somatic variants for this specimen: 491 protein-altering or splice-affecting, 239 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 448, Silent 239, Nonsense Mutation 35, Intron 14, RNA 6, 5'Flank 3, 3'UTR 3, 3'Flank 2, Splice Site 2, In Frame Del 1, 5'UTR 1, Translation Start Site 1.

Variants (750 of 759; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 386/387 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 383/385 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 143/369 reads (39%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 28/350 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs587777790, CM130265, COSV55877290; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SAMD9 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 118/330 reads (36%) | catalogued as rs1186536794, COSV66076161; ClinVar: pathogenic; called by muse, varscan2
- AAAS | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 165/374 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs748222885; called by muse, varscan2
- ABO | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 275/617 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV71743466; called by muse, mutect2
- ABO | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 272/617 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs578090581; called by muse, mutect2
- ACACA | c.6745C>T p.R2249C | Missense Mutation (SNP) | VAF 186/410 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1165714087; called by muse, mutect2, varscan2
- ACTL8 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 253/512 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64862748; called by muse, mutect2, varscan2
- ADAM18 | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 131/300 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs752996370, COSV55844420, COSV55851975; called by muse, mutect2, varscan2
- ADAM7 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 162/349 reads (46%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.672); catalogued as COSV99445097; called by muse, mutect2, varscan2
- ADAMTS18 | c.2312C>T p.P771L | Missense Mutation (SNP) | VAF 139/324 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400194605; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 181/392 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as rs1205309238; called by muse, mutect2, varscan2
- ADGRL2 | c.1933G>A p.E645K (on ENST00000370717 / NM_001366005.1; = p.E632K on NM_012302.4) | Missense Mutation (SNP) | VAF 163/362 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99590770; called by muse, mutect2, varscan2
- AGRN | c.5233C>T p.R1745C | Missense Mutation (SNP) | VAF 291/593 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs765077103; called by muse, mutect2, varscan2
- ALDH16A1 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 349/739 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs770180307; called by muse, mutect2, varscan2
- ALOX15 | c.1823A>G p.Q608R | Missense Mutation (SNP) | VAF 154/352 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.472); catalogued as rs755005094; called by muse, mutect2, varscan2
- ALPI | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 255/635 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV55014023; called by muse, mutect2, varscan2
- ALS2 | c.1865C>T p.S622F | Missense Mutation (SNP) | VAF 163/350 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1439273774, COSV51884319; called by muse, mutect2, varscan2
- AP2A2 | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 239/512 reads (47%) | catalogued as COSV59960126; called by muse, mutect2, varscan2
- ASB18 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 342/816 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs751717266; called by muse, mutect2, varscan2
- ASB5 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 152/305 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774259355, COSV56673280; called by muse, mutect2, varscan2
- ASIC4 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 137/394 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs777793535, COSV61731810; called by muse, mutect2, varscan2
- ATP2A3 | c.2160G>A p.M720I | Missense Mutation (SNP) | VAF 244/499 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs778581081; called by muse, mutect2, varscan2
- BAZ1B | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 319/540 reads (59%) | SIFT tolerated (0.19); PolyPhen benign (0.084); catalogued as rs782409459; called by muse, mutect2, varscan2
- BRINP1 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 144/322 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1422923029, COSV56314632; called by muse, mutect2, varscan2
- BSN | c.10654G>A p.A3552T | Missense Mutation (SNP) | VAF 247/500 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs774778213, COSV99608870; called by muse, mutect2, varscan2
- BTBD8 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.819); catalogued as COSV61546128; called by muse, mutect2, varscan2
- C12orf42 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 140/339 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.047); catalogued as COSV100172484; called by muse, mutect2, varscan2
- C3 | c.2983G>A p.V995I | Missense Mutation (SNP) | VAF 218/482 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs759285914, COSV55572475; called by muse, mutect2, varscan2
- CACNA1C | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 175/404 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1310223974, COSV59791416; called by muse, mutect2, varscan2
- CACNA1F | c.2461G>A p.E821K | Missense Mutation (SNP) | VAF 222/224 reads (99%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as COSV59905541; called by muse, varscan2
- CACNA2D4 | c.1988G>A p.G663E | Missense Mutation (SNP) | VAF 199/404 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54950879; called by muse, mutect2, varscan2
- CCDC185 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 334/714 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.091); catalogued as COSV64821919; called by muse, mutect2, varscan2
- CCDC3 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 161/343 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV66560727; called by muse, mutect2, varscan2
- CCIN | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 247/527 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as rs1450270569, COSV58724961; called by muse, mutect2, varscan2
- CD40LG | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 107/107 reads (100%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs752210787, CD961880, COSV65698933; called by muse, mutect2, varscan2
- CEP170 | c.880A>G p.I294V | Missense Mutation (SNP) | VAF 237/498 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.243); catalogued as rs577000363; called by muse, mutect2, varscan2
- CLEC14A | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 294/645 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as COSV100643681; called by muse, mutect2, varscan2
- CLSTN3 | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 173/381 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1204956241; called by muse, mutect2, varscan2
- CNOT10 | c.1967G>A p.R656K | Missense Mutation (SNP) | VAF 218/441 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs1219969307; called by muse, mutect2, varscan2
- CNTN4 | c.1336G>A p.D446N | Missense Mutation (SNP) | VAF 135/281 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV61875871; called by muse, mutect2, varscan2
- COL1A2 | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 389/664 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1437648908; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 261/586 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV52110091, COSV52111311; called by muse, mutect2, varscan2
- CPT2 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 216/439 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773966429, COSV53760302; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF1 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 450/1024 reads (44%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as rs772621335; called by muse, mutect2
- CSMD3 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 126/498 reads (25%) | catalogued as COSV52186754, COSV52248040; called by muse, mutect2, varscan2
- CT47B1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 209/210 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.759); catalogued as rs542629895; called by muse, mutect2, varscan2
- CYP11B2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 180/496 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1311264822; called by muse, mutect2, varscan2
- DCST1 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 266/591 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1160179576; called by muse, mutect2, varscan2
- DMD | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV99918234; called by muse, mutect2, varscan2
- DNAH5 | c.7916G>A p.R2639Q | Missense Mutation (SNP) | VAF 199/366 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs140968268, COSV54202500; called by muse, mutect2, varscan2
- DNAH8 | c.3296T>C p.I1099T | Missense Mutation (SNP) | VAF 201/412 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs757754264; called by muse, mutect2, varscan2
- DNAH8 | c.10447G>A p.E3483K | Missense Mutation (SNP) | VAF 130/306 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59470485; called by muse, mutect2, varscan2
- DOCK4 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 219/692 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV70323885; called by muse, mutect2, varscan2
- DPP10 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 151/347 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59722322; called by muse, mutect2, varscan2
- DPYS | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 209/715 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs765884757, COSV60906455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DSC1 | c.2578G>A p.G860S | Missense Mutation (SNP) | VAF 260/595 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs766767693; called by muse, mutect2, varscan2
- EFCAB12 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 291/595 reads (49%) | catalogued as rs201855762; called by muse, mutect2, varscan2
- EFR3A | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 136/527 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372996175; called by muse, mutect2, varscan2
- ELF5 | c.625G>A p.E209K (on ENST00000312319 / NM_198381.2; = p.E199K on NM_001422.4) | Missense Mutation (SNP) | VAF 231/503 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99141310; called by muse, mutect2, varscan2
- EMB | c.682T>A p.L228M | Missense Mutation (SNP) | VAF 264/668 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV100297098; called by muse, mutect2, varscan2
- EPHA1 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 634/636 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as rs759092209; called by muse, mutect2, varscan2
- EPYC | c.580C>T p.R194* | Nonsense Mutation (SNP) | VAF 205/457 reads (45%) | catalogued as rs779578980, COSV53799693; called by muse, mutect2, varscan2
- EXOC6B | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs779466855; called by muse, mutect2, varscan2
- EYA1 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 389/613 reads (63%) | catalogued as CM980645, COSV100378534, COSV100379912, COSV58162866; called by muse, mutect2, varscan2
- FAM83B | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 201/565 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753104783, COSV60922418; called by muse, mutect2, varscan2
- FAM89B | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 525/1040 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.837); catalogued as rs1308626906; called by muse, mutect2, varscan2
- FAT3 | c.7049G>A p.R2350Q | Missense Mutation (SNP) | VAF 173/384 reads (45%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); catalogued as rs1451801313; called by muse, mutect2, varscan2
- FCN1 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 148/293 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as rs140379786; called by muse, mutect2, varscan2
- FHL5 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs746596116, COSV100459801; called by muse, mutect2, varscan2
- FOLH1 | c.1900dup p.S634Ffs*15 | Frame Shift Ins (INS) | VAF 80/233 reads (34%) | catalogued as rs1446664569; called by mutect2, pindel, varscan2
- GABRR3 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 28/406 reads (7%) | catalogued as COSV72084312; called by muse, mutect2
- GAD2 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 141/287 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV52150771; called by muse, mutect2, varscan2
- GALNTL6 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 227/457 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.06); catalogued as COSV101560008; called by muse, mutect2, varscan2
- GDF10 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 437/437 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.704); catalogued as rs1255618926; called by muse, mutect2, varscan2
- GJA8 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 245/554 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as rs782515955; called by muse, mutect2, varscan2
- GJB4 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 371/809 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as rs200953314; called by muse, mutect2, varscan2
- GLB1L2 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 165/369 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV56995292; called by muse, mutect2, varscan2
- GPR142 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 388/861 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1210262311; called by muse, mutect2, varscan2
- GPR61 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 253/495 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs143529971; called by muse, mutect2, varscan2
- GREB1 | c.2753C>T p.P918L | Missense Mutation (SNP) | VAF 593/995 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs375384889; called by muse, mutect2, varscan2
- GRIA1 | c.2671C>T p.P891S | Missense Mutation (SNP) | VAF 344/344 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.434); catalogued as COSV99600734; called by muse, mutect2, varscan2
- GRIN3A | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 292/614 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.08); catalogued as rs1402016826, COSV100702013; called by muse, mutect2, varscan2
- GRXCR1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 288/573 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs773349384; called by muse, mutect2, varscan2
- GSG1 | c.113C>T p.S38L (on ENST00000651961 / NM_001080555.4; = p.S25L on NM_031289.5) | Missense Mutation (SNP) | VAF 184/454 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs150478386; called by muse, mutect2, varscan2
- GUCA1C | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 198/432 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs1265768088, COSV51712957; called by muse, mutect2, varscan2
- GUCY2D | c.1957-1G>A p.X653_splice | Splice Site (SNP) | VAF 175/352 reads (50%) | catalogued as rs61749759, CS002137, CS002138, COSV99643916; ClinVar: not provided; called by muse, mutect2, varscan2
- HCAR2 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 59/522 reads (11%) | catalogued as rs765816524, COSV61024952; called by muse, mutect2, varscan2
- HOXB1 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 32/675 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.068); catalogued as rs765050616, COSV53317864; called by muse, mutect2
- HSPA2 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 220/487 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.087); catalogued as COSV99904656; called by muse, mutect2, varscan2
- IDO1 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 265/549 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53713747; called by muse, mutect2, varscan2
- IGLL1 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 300/791 reads (38%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs758781859, COSV50769746; called by muse, mutect2
- IL1RL2 | c.1264T>C p.F422L | Missense Mutation (SNP) | VAF 166/306 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1490844923; called by muse, mutect2, varscan2
- IMPG1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 237/237 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64059238; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); catalogued as COSV104431183, COSV67330611; called by muse, mutect2, varscan2
- KCNB2 | c.1834G>A p.D612N | Missense Mutation (SNP) | VAF 556/860 reads (65%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.983); catalogued as rs140075333; called by muse, mutect2, varscan2
- KCNH6 | c.2171C>T p.S724F | Missense Mutation (SNP) | VAF 243/484 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV59005895; called by muse, mutect2, varscan2
- KIAA0825 | c.1052C>T p.S351F | Missense Mutation (SNP) | VAF 171/554 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV56950528; called by muse, mutect2, varscan2
- KIAA0930 | c.637A>T p.K213* (on ENST00000336156 / NM_001009880.2; = p.K218* on NM_015264.2) | Nonsense Mutation (SNP) | VAF 220/440 reads (50%) | catalogued as rs780119054; called by muse, mutect2, varscan2
- KIF4B | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 394/394 reads (100%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.882); catalogued as rs541398809, COSV70528412; called by muse, mutect2, varscan2
- KIR2DL3 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 41/192 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs776687200, COSV60896036; called by muse, varscan2
- KLHL3 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 269/269 reads (100%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.791); catalogued as COSV59051036; called by muse, mutect2, varscan2
- KMT2C | c.7703G>A p.G2568E | Missense Mutation (SNP) | VAF 397/673 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV51366586, COSV51424113; called by muse, mutect2, varscan2
- KRT31 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 237/523 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as COSV52436185; called by muse, mutect2, varscan2
- KRT34 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 168/327 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs866265957, COSV101222713, COSV67449443; called by muse, mutect2, varscan2
- KRTAP23-1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 127/283 reads (45%) | PolyPhen benign (0.011); catalogued as rs750836659, COSV100492653; called by muse, mutect2, varscan2
- LILRB2 | c.1148T>C p.M383T | Missense Mutation (SNP) | VAF 277/586 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs1028997873; called by muse, mutect2, varscan2
- LRFN2 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 276/655 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751273503; called by muse, mutect2, varscan2
- LRP1B | c.10468C>T p.P3490S | Missense Mutation (SNP) | VAF 148/323 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101261909; called by muse, mutect2, varscan2
- LTF | c.1724G>A p.G575E | Missense Mutation (SNP) | VAF 170/337 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99207231; called by muse, mutect2, varscan2
- MACF1 | c.12026A>G p.D4009G (on ENST00000372915; = p.D1942G on NM_012090.5) | Missense Mutation (SNP) | VAF 194/432 reads (45%) | catalogued as rs748658509; called by muse, varscan2
- MAGEE2 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 279/279 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV64897995; called by muse, mutect2, varscan2
- MAOA | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 133/133 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs140295792, COSV58641530; called by muse, mutect2, varscan2
- MAPT | c.2222G>A p.R741K (on ENST00000262410 / NM_001377265.1; = p.R349K on NM_005910.5) | Missense Mutation (SNP) | VAF 188/460 reads (41%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.753); catalogued as COSV99291558; called by muse, mutect2, varscan2
- MARCO | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 202/467 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254250452, COSV100503572, COSV59056535; called by muse, mutect2, varscan2
- MDC1 | c.949C>T p.H317Y | Missense Mutation (SNP) | VAF 398/966 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV64526333; called by muse, mutect2, varscan2
- ME1 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 109/109 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs145714966; called by muse, mutect2, varscan2
- MEIOC | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 164/368 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV63441841; called by muse, mutect2, varscan2
- MGAT4C | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 195/442 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV59833687; called by muse, mutect2, varscan2
- MIDEAS | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 316/698 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs751165860, COSV54098999; called by muse, varscan2
- MMRN1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 146/320 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV104392866; called by muse, mutect2, varscan2
- MXRA5 | c.6565G>A p.D2189N | Missense Mutation (SNP) | VAF 197/197 reads (100%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.915); catalogued as rs1482162845; called by muse, mutect2, varscan2
- MYH1 | c.5671G>A p.E1891K | Missense Mutation (SNP) | VAF 73/136 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56855015; called by muse, mutect2, varscan2
- MYH8 | c.3544G>A p.E1182K | Missense Mutation (SNP) | VAF 157/342 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67970669; called by muse, mutect2, varscan2
- MYLK3 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 159/343 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as rs1355220180; called by muse, mutect2, varscan2
- NAT10 | c.2362C>T p.P788S | Missense Mutation (SNP) | VAF 176/384 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0.01); catalogued as rs867498285; called by muse, mutect2, varscan2
- NCDN | c.1226C>T p.S409F | Missense Mutation (SNP) | VAF 295/625 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.916); catalogued as COSV61936231; called by muse, mutect2, varscan2
- NETO1 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 98/224 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100199031; called by muse, mutect2, varscan2
- NEXMIF | c.4174C>T p.H1392Y | Missense Mutation (SNP) | VAF 281/282 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as rs868098984; called by muse, mutect2, varscan2
- NISCH | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 342/726 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1183478558; called by muse, varscan2
- NLGN4X | c.1730G>A p.R577K | Missense Mutation (SNP) | VAF 223/225 reads (99%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV52025367; called by muse, mutect2, varscan2
- NLRP3 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 241/547 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as rs762512734, COSV60229623; called by muse, mutect2, varscan2
- NPHS1 | c.3569G>A p.G1190E | Missense Mutation (SNP) | VAF 137/318 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as rs1353178621, COSV62287681; called by muse, mutect2, varscan2
- NR1H2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 389/814 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs760182372, COSV53801555; called by muse, varscan2
- OR10D3 | c.336C>A p.C112* | Nonsense Mutation (SNP) | VAF 184/397 reads (46%) | catalogued as rs1292080091; called by muse, mutect2, varscan2
- OR13C9 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 127/287 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV99403468; called by muse, mutect2, varscan2
- OR2M5 | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 120/294 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV63546077; called by muse, varscan2
- OR4D5 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 288/585 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs768699202, COSV58305938; called by muse, mutect2, varscan2
- OR4X1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 215/510 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV60723863; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 160/349 reads (46%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, mutect2, varscan2
- OR51F2 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 170/403 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs767787431, COSV59063793; called by muse, mutect2, varscan2
- OR5B17 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 149/324 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); catalogued as rs764197115; called by muse, mutect2, varscan2
- OR5H14 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 69/183 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs541342101, COSV71193554, COSV71194506; called by muse, mutect2, varscan2
- OR5H2 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 189/424 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV62351535; called by muse, mutect2, varscan2
- OTOF | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 463/743 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55522067; called by muse, mutect2, varscan2
- PAX7 | c.112G>T p.V38F | Missense Mutation (SNP) | VAF 253/560 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351630881; called by muse, mutect2
- PCDH17 | c.2349G>A p.M783I | Missense Mutation (SNP) | VAF 273/578 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV64972304; called by muse, mutect2, varscan2
- PCDHAC1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 370/370 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs140626189, COSV53845270; called by muse, mutect2, varscan2
- PCDHB6 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 603/604 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99172745; called by muse, mutect2, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 179/668 reads (27%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, mutect2, varscan2
- PCDHB8 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 113/564 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.158); catalogued as rs1554280873; called by muse, mutect2
- PCDHGB3 | c.2146C>T p.R716* | Nonsense Mutation (SNP) | VAF 365/365 reads (100%) | catalogued as rs1208837944, COSV53894285; called by muse, mutect2, varscan2
- PCLO | c.8024C>T p.S2675F | Missense Mutation (SNP) | VAF 200/576 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV61640639; called by muse, mutect2, varscan2
- PCLO | c.5290G>A p.G1764S | Missense Mutation (SNP) | VAF 246/690 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV61629062; called by muse, mutect2, varscan2
- PCNX2 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 237/516 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.575); catalogued as COSV50800921; called by muse, mutect2, varscan2
- PGLYRP4 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 217/493 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62834456; called by muse, mutect2, varscan2
- PID1 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 160/420 reads (38%) | PolyPhen benign (0); catalogued as COSV62475226; called by muse, mutect2, varscan2
- PIK3R5 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 254/500 reads (51%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as rs1395300937; called by muse, varscan2
- PIK3R5 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 260/566 reads (46%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs751907609, COSV52652124; called by muse, varscan2
- PIWIL2 | c.1840G>A p.A614T | Missense Mutation (SNP) | VAF 148/343 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1465787639; called by muse, mutect2, varscan2
- PKD1L1 | c.5809C>T p.H1937Y | Missense Mutation (SNP) | VAF 209/470 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56977570; called by muse, mutect2, varscan2
- PLXNC1 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 101/258 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs760717500, COSV51570639; called by muse, mutect2, varscan2
- POM121L2 | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 256/486 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs937423049, COSV101079309; called by muse, mutect2, varscan2
- POTEG | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 228/1792 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.33); catalogued as COSV101611993; called by muse, varscan2
- PREX2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 193/575 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as COSV55756774, COSV55797706; called by muse, mutect2, varscan2
- PRKD1 | c.2374C>A p.Q792K | Missense Mutation (SNP) | VAF 78/414 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV59591051; called by muse, mutect2, varscan2
- PRKD1 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776034417, COSV59573695; called by muse, mutect2, varscan2
- PTGER3 | c.1081G>A p.E361K (on ENST00000628037 / NM_198717.2; = p.E370K on NM_198716.2) | Missense Mutation (SNP) | VAF 147/317 reads (46%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs771757558, COSV63388000; called by muse, mutect2, varscan2
- PTPRK | c.2743C>T p.R915* (on ENST00000368215 / NM_001291984.2; = p.R916* on NM_002844.4) | Nonsense Mutation (SNP) | VAF 110/110 reads (100%) | catalogued as rs1397159308, COSV63893274; called by muse, mutect2, varscan2
- PTPRR | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 119/308 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV51738549; called by muse, mutect2, varscan2
- PXDNL | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 389/618 reads (63%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as COSV62500987; called by muse, mutect2, varscan2
- QRICH2 | c.1312G>A p.G438R | Missense Mutation (SNP) | VAF 308/625 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1364166103; called by muse, mutect2, varscan2
- RFX6 | c.2368G>A p.G790R | Missense Mutation (SNP) | VAF 169/169 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100264096; called by muse, mutect2, varscan2
- RGS4 | c.421A>G p.M141V | Missense Mutation (SNP) | VAF 214/479 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV104425574; called by muse, mutect2, varscan2
- RP1L1 | c.4772C>T p.P1591L | Missense Mutation (SNP) | VAF 356/746 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.199); catalogued as COSV66760002; called by muse, mutect2, varscan2
- RTL1 | c.3715G>A p.D1239N | Missense Mutation (SNP) | VAF 381/727 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as rs775741559, COSV66017479; called by muse, mutect2, varscan2
- RTL1 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 242/520 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV66016815; called by muse, mutect2, varscan2
- SCD5 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 114/244 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs762891080, COSV56726239; called by muse, varscan2
- SCN9A | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.831); catalogued as COSV100313435, COSV57610049; called by muse, mutect2, varscan2
- SEMA3E | c.1258A>G p.K420E | Missense Mutation (SNP) | VAF 284/491 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.439); catalogued as COSV57081254; called by muse, mutect2, varscan2
- SERPINB4 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 109/239 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs868227362, COSV61984277; called by muse, mutect2, varscan2
- SHISA6 | c.1249G>A p.E417K (on ENST00000409168 / NM_001173461.1; = p.E468K on NM_207386.4) | Missense Mutation (SNP) | VAF 360/726 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs929688938, COSV69389395; called by muse, mutect2, varscan2
- SHKBP1 | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 400/797 reads (50%) | catalogued as rs1206915794; called by muse, mutect2, varscan2
- SLC22A1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 286/286 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs375891889; called by muse, mutect2, varscan2
- SLC2A9 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 198/431 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV53328793; called by muse, mutect2, varscan2
- SLFN11 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 208/458 reads (45%) | catalogued as rs754420565; called by muse, mutect2, varscan2
- SPHKAP | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 207/494 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as rs770444711; called by muse, mutect2, varscan2
- SPINK5 | c.2999C>T p.P1000L | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as rs1233347708; called by muse, mutect2, varscan2
- SPN | c.153T>G p.S51R | Missense Mutation (SNP) | VAF 284/580 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1481054377; called by muse, mutect2, varscan2
- SPRED1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 191/447 reads (43%) | catalogued as rs148646547, CM1210087, COSV54437715; called by muse, mutect2, varscan2
- TAF13 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 73/224 reads (33%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.786); catalogued as rs766023319; called by muse, mutect2, varscan2
- TAOK1 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 214/430 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs777374325; called by muse, mutect2, varscan2
- TBCD | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 187/366 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs769827032; called by muse, mutect2, varscan2
- TCEA3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 278/567 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.094); catalogued as COSV65840931; called by muse, mutect2, varscan2
- TGM5 | c.1942G>A p.E648K (on ENST00000220420 / NM_201631.4; = p.E566K on NM_004245.4) | Missense Mutation (SNP) | VAF 218/475 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV55009673; called by muse, mutect2, varscan2
- THBS1 | c.3176C>T p.S1059L | Missense Mutation (SNP) | VAF 264/556 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as rs1339729749; called by muse, varscan2
- TNC | c.1304G>A p.S435N | Missense Mutation (SNP) | VAF 258/560 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as rs1359511347; called by muse, mutect2, varscan2
- TNFSF4 | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 248/558 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as rs866439624; called by muse, mutect2, varscan2
- TNR | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 275/560 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs746751518, COSV54872462, COSV54893268; called by muse, mutect2, varscan2
- TNR | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 217/499 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.518); catalogued as rs1461282624; called by muse, mutect2, varscan2
- TOM1 | c.704C>T p.S235L | Missense Mutation (SNP) | VAF 195/454 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs746325920; called by muse, mutect2, varscan2
- TONSL | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 282/886 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV68048469; called by muse, mutect2, varscan2
- TPR | c.2227C>T p.H743Y | Missense Mutation (SNP) | VAF 223/477 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV66602025; called by muse, mutect2, varscan2
- TPTE | c.695G>A p.R232K (on ENST00000618007 / NM_199261.4; = p.R214K on NM_199259.4) | Missense Mutation (SNP) | VAF 54/413 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1460256558; called by muse, varscan2
- TPTE2 | c.1063C>T p.R355* (on ENST00000400230 / NM_199254.2; = p.R278* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 70/244 reads (29%) | catalogued as rs759307577; called by muse, mutect2, varscan2
- TTC24 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 283/664 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs1483568396; called by muse, mutect2, varscan2
- TTN | c.66680G>A p.R22227Q (on ENST00000591111; = p.R14803Q on NM_003319.4) | Missense Mutation (SNP) | VAF 199/404 reads (49%) | PolyPhen benign (0.396); catalogued as rs763316990, COSV60061049; called by muse, mutect2, varscan2
- TTN | c.51169G>A p.E17057K (on ENST00000591111; = p.E9633K on NM_003319.4) | Missense Mutation (SNP) | VAF 157/389 reads (40%) | PolyPhen probably damaging (0.994); catalogued as COSV60199420; called by muse, mutect2
- TTN | c.37579G>A p.E12527K (on ENST00000591111; = p.E5103K on NM_003319.4) | Missense Mutation (SNP) | VAF 197/391 reads (50%) | PolyPhen possibly damaging (0.54); catalogued as COSV60379055; called by muse, mutect2, varscan2
- TULP1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 190/338 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs868771267, COSV57691716; called by muse, mutect2, varscan2
- UGT2A3 | c.1057G>A p.D353N | Missense Mutation (SNP) | VAF 140/315 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV52360148; called by muse, mutect2, varscan2
- UNC13C | c.3781G>A p.G1261R | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV52844021; called by muse, mutect2, varscan2
- UNC5CL | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 330/615 reads (54%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as rs767528036, COSV55109870; called by muse, mutect2, varscan2
- USH2A | c.14348C>T p.S4783F | Missense Mutation (SNP) | VAF 138/258 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as rs373551475; called by muse, mutect2, varscan2
- USP29 | c.1736C>T p.P579L | Missense Mutation (SNP) | VAF 169/369 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as rs754668181; called by muse, mutect2, varscan2
- VWA5B1 | c.3175T>C p.S1059P (on ENST00000375079; = p.S1054P on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 190/412 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs530582281; called by muse, mutect2, varscan2
- WDR87 | c.5293G>A p.E1765K | Missense Mutation (SNP) | VAF 259/537 reads (48%) | SIFT tolerated (0.92); PolyPhen benign (0.029); catalogued as rs973446632; called by muse, mutect2, varscan2
- XRN2 | c.1956C>G p.F652L | Missense Mutation (SNP) | VAF 161/357 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101018323, COSV65869394; called by muse, mutect2, varscan2
- ZBTB14 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.218); catalogued as rs772807095; called by muse, mutect2, varscan2
- ZDHHC22 | c.715G>C p.G239R | Missense Mutation (SNP) | VAF 286/659 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60058290; called by muse, mutect2, varscan2
- ZNF180 | c.428C>T p.T143I | Missense Mutation (SNP) | VAF 193/373 reads (52%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.735); catalogued as rs768681387; called by muse, mutect2, varscan2
- ZNF208 | c.1087C>T p.H363Y | Missense Mutation (SNP) | VAF 190/418 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101237059, COSV68106286; called by muse, mutect2, varscan2
- ZNF382 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.247); catalogued as COSV53087762, COSV99497571; called by muse, mutect2
- ZNF544 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 160/311 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.018); catalogued as COSV99517179; called by muse, mutect2, varscan2
- ZNF560 | c.534G>A p.W178* | Nonsense Mutation (SNP) | VAF 96/232 reads (41%) | catalogued as COSV56865962; called by muse, mutect2, varscan2
- ZNF781 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 232/482 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.225); catalogued as rs1205986398, COSV62201508; called by muse, mutect2, varscan2
- ZNF93 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 132/268 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs879037548; called by muse, mutect2, varscan2
- ZNF98 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 173/416 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.404); catalogued as COSV63337207; called by muse, mutect2, varscan2
- ZSCAN5B | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 221/436 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV61999079; called by muse, mutect2, varscan2
- AADACL3 | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 194/437 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ABCA4 | c.6572G>A p.G2191E | Missense Mutation (SNP) | VAF 151/353 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 286/576 reads (50%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ACAN | c.1750A>C p.T584P | Missense Mutation (SNP) | VAF 186/431 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACCS | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 154/369 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADH1B | c.945G>A p.W315* | Nonsense Mutation (SNP) | VAF 101/196 reads (52%) | called by muse, mutect2, varscan2
- AL121845.3 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 271/589 reads (46%) | called by muse, mutect2, varscan2
- ALDH3A2 | c.1013C>T p.P338L | Missense Mutation (SNP) | VAF 177/383 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKRD18A | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 96/244 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ANKRD30A | c.4076G>A p.R1359K (on ENST00000611781; = p.R1303K on NM_052997.2) | Missense Mutation (SNP) | VAF 107/240 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ANKRD30B | c.2639C>T p.S880F | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ANKRD44 | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 230/538 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- ANPEP | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 219/451 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- APAF1 | c.332G>A p.R111K (on ENST00000551964 / NM_181861.2; = p.R100K on NM_001160.3) | Missense Mutation (SNP) | VAF 133/274 reads (49%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP44 | c.1431G>A p.M477I | Missense Mutation (SNP) | VAF 212/544 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.005); called by muse, mutect2
- ASTN2 | c.3766G>A p.D1256N (on ENST00000313400 / NM_001365069.1; = p.D1205N on NM_014010.5) | Missense Mutation (SNP) | VAF 127/325 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BDKRB2 | c.984C>A p.N328K | Missense Mutation (SNP) | VAF 239/538 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BSN | c.9403C>T p.P3135S | Missense Mutation (SNP) | VAF 346/739 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C10orf71 | c.226C>T p.Q76* | Nonsense Mutation (SNP) | VAF 269/269 reads (100%) | called by muse, mutect2, varscan2
- C19orf18 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 161/316 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- C3orf80 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 331/711 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- CACNA1G | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 172/350 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- CACNA1I | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 207/409 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1I | c.5698G>A p.G1900R | Missense Mutation (SNP) | VAF 187/363 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CACNA2D3 | c.2588G>A p.G863E | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- CACNB1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 185/443 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLB | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 209/451 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CCDC157 | c.109T>C p.F37L | Missense Mutation (SNP) | VAF 348/703 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- CCDC73 | c.2714C>A p.S905* | Nonsense Mutation (SNP) | VAF 171/383 reads (45%) | called by muse, mutect2, varscan2
- CCNB3 | c.2276T>C p.V759A | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDC16 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 146/360 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC42BPA | c.970A>G p.S324G | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CEACAM20 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 326/688 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CEMIP | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 185/454 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP112 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- CFAP92 | c.1895T>G p.L632R | Missense Mutation (SNP) | VAF 289/588 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFHR5 | c.909G>A p.M303I | Missense Mutation (SNP) | VAF 171/387 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CHD5 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 298/689 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CHMP1B | c.106A>T p.I36F | Missense Mutation (SNP) | VAF 279/575 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- CILP | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 141/289 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, varscan2
- CLEC4D | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 146/293 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CNGB3 | c.2242G>T p.E748* | Nonsense Mutation (SNP) | VAF 164/860 reads (19%) | called by muse, mutect2
- COG5 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 73/250 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COIL | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 277/554 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- COL27A1 | c.4152C>A p.P1384= | Splice Region (SNP) | VAF 271/543 reads (50%) | called by muse, mutect2, varscan2
- COL4A6 | c.2315_2324del p.H772Lfs*20 | Frame Shift Del (DEL) | VAF 178/182 reads (98%) | called by mutect2, pindel, varscan2
- COL8A2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 342/694 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRYBG3 | c.8825G>A p.G2942E | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- CTC1 | c.3302C>T p.P1101L | Missense Mutation (SNP) | VAF 269/549 reads (49%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CYP4A11 | c.819A>C p.Q273H | Missense Mutation (SNP) | VAF 112/261 reads (43%) | SIFT tolerated (0.81); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DAPK1 | c.295G>A p.G99S | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCC | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 177/377 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- DEPDC4 | c.409G>A p.G137R | Missense Mutation (SNP) | VAF 140/321 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- DIRAS2 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 202/414 reads (49%) | called by muse, mutect2, varscan2
- DLEC1 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 230/485 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DNAJC13 | c.4117C>A p.L1373I | Missense Mutation (SNP) | VAF 90/291 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DPYS | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 135/483 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DSCAM | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 126/287 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG1 | c.2254G>A p.G752R | Missense Mutation (SNP) | VAF 201/443 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EFNB2 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 193/448 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EGFR | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 129/314 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHMT1 | c.1521T>G p.D507E | Missense Mutation (SNP) | VAF 264/511 reads (52%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ELFN2 | c.1907C>T p.S636F | Missense Mutation (SNP) | VAF 322/683 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ELOA2 | c.1762C>T p.H588Y | Missense Mutation (SNP) | VAF 195/393 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ENTR1 | c.1087C>T p.Q363* (on ENST00000357365 / NM_001039707.2; = p.Q340* on NM_006643.4) | Nonsense Mutation (SNP) | VAF 246/443 reads (56%) | called by muse, mutect2, varscan2
- ERVV-1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 90/398 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, varscan2
- EYS | c.4213C>T p.P1405S | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- FAM193A | c.2561T>A p.F854Y | Missense Mutation (SNP) | VAF 208/399 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAM221A | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 258/479 reads (54%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBXO16 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 210/453 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FGD5 | c.1807T>C p.S603P | Missense Mutation (SNP) | VAF 223/495 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- FGF9 | c.373T>A p.Y125N | Missense Mutation (SNP) | VAF 127/256 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FLG | c.5129G>A p.G1710E | Missense Mutation (SNP) | VAF 172/332 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- FLT3 | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 240/526 reads (46%) | called by muse, mutect2
- FRMPD1 | c.3574G>T p.G1192C | Missense Mutation (SNP) | VAF 191/441 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FSIP2 | c.8168A>G p.K2723R | Missense Mutation (SNP) | VAF 208/474 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FSIP2 | c.16654G>A p.E5552K | Missense Mutation (SNP) | VAF 97/246 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GALNT13 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 204/444 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- GALNT13 | c.1187C>T p.S396L | Missense Mutation (SNP) | VAF 133/297 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.239); called by muse, varscan2
- GALNT13 | c.1245A>T p.E415D | Missense Mutation (SNP) | VAF 158/324 reads (49%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, varscan2
- GARRE1 | c.2074C>T p.P692S | Missense Mutation (SNP) | VAF 302/682 reads (44%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GIPR | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 310/660 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLDN | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 175/407 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0.007); called by muse, varscan2
- GLMP | c.297_299del p.L100del | In Frame Del (DEL) | VAF 73/673 reads (11%) | called by mutect2, pindel, varscan2
- GPR171 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 179/434 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR55 | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 290/531 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK2 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 264/264 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HCAR3 | c.1059G>A p.W353* | Nonsense Mutation (SNP) | VAF 192/485 reads (40%) | called by muse, mutect2, varscan2
- HCN4 | c.3419_3421dup p.R1140dup | In Frame Ins (INS) | VAF 307/696 reads (44%) | called by mutect2, pindel, varscan2
- HDAC9 | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- HECTD4 | c.13081C>T p.P4361S | Missense Mutation (SNP) | VAF 213/496 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- HECW2 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 166/354 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- HERC2 | c.1725G>A p.W575* | Nonsense Mutation (SNP) | VAF 330/704 reads (47%) | called by muse, mutect2, varscan2
- HEYL | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 348/719 reads (48%) | SIFT tolerated (0.75); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HIVEP2 | c.3763T>C p.Y1255H | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.726); called by muse, mutect2
- HNRNPA2B1 | c.300G>T p.E100D (on ENST00000354667 / NM_031243.3; = p.E88D on NM_002137.4) | Missense Mutation (SNP) | VAF 21/294 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2
- HOXC6 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 312/640 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSPA14 | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HTR3B | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 206/461 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- IDO2 | c.452A>G p.N151S (on ENST00000389060; = p.N164S on NM_194294.2) | Missense Mutation (SNP) | VAF 150/328 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFIH1 | c.929C>G p.P310R | Missense Mutation (SNP) | VAF 213/442 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- IGKC | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 233/736 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- IL9R | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 324/740 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- INPP5D | c.2698C>T p.P900S (on ENST00000445964 / NM_001017915.3; = p.P899S on NM_005541.5) | Missense Mutation (SNP) | VAF 167/336 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- IQCA1 | c.407A>T p.K136I | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- IQCA1L | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 350/350 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ITGA8 | c.2372G>A p.G791E | Missense Mutation (SNP) | VAF 96/224 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ITGB3 | c.363T>G p.D121E | Missense Mutation (SNP) | VAF 98/223 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- JPH1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 425/1368 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- KCNIP4 | c.259C>T p.L87F | Missense Mutation (SNP) | VAF 182/335 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- KCTD2 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 314/670 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- KIAA1755 | c.1598C>T p.P533L | Missense Mutation (SNP) | VAF 175/462 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA1755 | c.1597C>T p.P533S | Missense Mutation (SNP) | VAF 172/460 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KIF1A | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 255/660 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIN | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KLF7 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 333/622 reads (54%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP10-11 | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 265/559 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- KRTAP4-9 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 323/641 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- LAMB2 | c.3206C>T p.P1069L | Missense Mutation (SNP) | VAF 311/655 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- LCOR | c.4492A>T p.K1498* | Nonsense Mutation (SNP) | VAF 49/288 reads (17%) | called by muse, mutect2, varscan2
- LIPK | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 79/79 reads (100%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIPT1 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 191/380 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRIG1 | c.1162A>G p.T388A | Missense Mutation (SNP) | VAF 24/413 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.098); called by muse, mutect2
- LRP1B | c.1232G>A p.R411K | Missense Mutation (SNP) | VAF 80/182 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRC3B | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 185/431 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC4C | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 208/429 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRRC9 | c.3148C>T p.H1050Y | Missense Mutation (SNP) | VAF 134/293 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- LY86 | c.107G>A p.S36N | Missense Mutation (SNP) | VAF 193/729 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- LYPD8 | c.551A>C p.E184A | Missense Mutation (SNP) | VAF 247/560 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MAN1A1 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 140/140 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARK1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 236/537 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- MAT1A | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 167/167 reads (100%) | called by muse, mutect2, varscan2
- MATN1 | c.1259G>A p.R420K | Missense Mutation (SNP) | VAF 217/445 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MBD6 | c.2644A>T p.S882C | Missense Mutation (SNP) | VAF 332/723 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- MCRS1 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 202/459 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MEIKIN | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MFSD6L | c.1678G>A p.E560K | Missense Mutation (SNP) | VAF 236/493 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- MIER2 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 367/735 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MLNR | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 457/875 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- MLPH | c.1228G>A p.D410N | Missense Mutation (SNP) | VAF 308/522 reads (59%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- MOGAT2 | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 227/496 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MROH5 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 503/798 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- MTUS2 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 291/604 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- MTUS2 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 296/668 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MUC16 | c.24584C>T p.S8195L | Missense Mutation (SNP) | VAF 212/471 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- MYCBPAP | c.2165G>A p.R722K | Missense Mutation (SNP) | VAF 130/259 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYH15 | c.3994G>A p.E1332K | Missense Mutation (SNP) | VAF 125/283 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- MYO1F | c.1657A>G p.K553E | Missense Mutation (SNP) | VAF 242/570 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- NBPF12 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- NELL1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 200/418 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- NEURL4 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 318/645 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NIBAN3 | c.1181T>A p.V394E | Missense Mutation (SNP) | VAF 290/599 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP2 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 409/890 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS2 | c.779G>A p.W260* | Nonsense Mutation (SNP) | VAF 249/608 reads (41%) | called by muse, mutect2, varscan2
- NOTCH1 | c.5890C>T p.P1964S | Missense Mutation (SNP) | VAF 324/692 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- NPIPA7 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- NPIPA7 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NR4A1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 414/809 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRIP1 | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 237/547 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRXN1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 336/735 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NUP214 | c.3895T>G p.S1299A | Missense Mutation (SNP) | VAF 265/582 reads (46%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NXPH1 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 239/521 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR10H1 | c.601G>A p.G201S | Missense Mutation (SNP) | VAF 287/569 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- OR10S1 | c.388A>C p.T130P | Missense Mutation (SNP) | VAF 236/475 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- OR11A1 | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 327/822 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- OR11H1 | c.282A>T p.K94N | Missense Mutation (SNP) | VAF 111/736 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- OR2G6 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 179/397 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- OR52E1 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 198/440 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- OR52E2 | c.29A>C p.H10P | Missense Mutation (SNP) | VAF 11/328 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- OR5H8 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 127/285 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8D4 | c.810G>T p.Q270H | Missense Mutation (SNP) | VAF 170/353 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- OR8J3 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OS9 | c.892G>A p.G298S | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.242); called by muse, mutect2
- OS9 | c.1589C>T p.P530L | Missense Mutation (SNP) | VAF 179/355 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OTOG | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 232/498 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAPOLA | c.292T>A p.F98I | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- PCDH11Y | c.560A>G p.N187S (on ENST00000400457 / NM_032973.2; = p.N176S on NM_032971.3) | Missense Mutation (SNP) | VAF 166/171 reads (97%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH15 | c.4628G>A p.G1543D (on ENST00000644397 / NM_001354429.2; = p.G1492D on NM_001142769.3) | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDH18 | c.2776G>A p.G926R | Missense Mutation (SNP) | VAF 153/297 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH7 | c.2039A>G p.E680G | Missense Mutation (SNP) | VAF 125/406 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCDHB8 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 109/566 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.298); called by muse, mutect2
- PCLO | c.13126G>A p.A4376T | Missense Mutation (SNP) | VAF 175/502 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE6C | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 252/252 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PDK2 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 233/489 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PKHD1L1 | c.7219C>T p.P2407S | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- PLEKHA6 | c.648T>G p.C216W | Missense Mutation (SNP) | VAF 310/635 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- PLEKHM1 | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 233/489 reads (48%) | called by muse, mutect2, varscan2
- PLXNA3 | c.2648C>T p.S883F | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- PON1 | c.636A>T p.E212D | Missense Mutation (SNP) | VAF 388/706 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.03); called by muse, mutect2
- PPP4R1 | c.1391C>T p.P464L (on ENST00000400556 / NM_001042388.3; = p.P447L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 201/418 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRAMEF6 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 191/631 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRDM8 | c.1136G>C p.G379A | Missense Mutation (SNP) | VAF 410/846 reads (48%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRDX1 | c.346T>G p.Y116D | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRQ | c.6350G>A p.G2117E (on ENST00000616559; = p.G2084E on NM_001145026.2) | Missense Mutation (SNP) | VAF 106/336 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2
- PTPRQ | c.6352G>A p.D2118N (on ENST00000616559; = p.D2085N on NM_001145026.2) | Missense Mutation (SNP) | VAF 110/340 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBBP8NL | c.1793A>G p.E598G | Missense Mutation (SNP) | VAF 208/468 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.559); called by mutect2, varscan2
- RGPD2 | c.4330G>A p.D1444N | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); called by mutect2, varscan2
- RGPD2 | c.4030G>A p.E1344K | Missense Mutation (SNP) | VAF 186/464 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGS12 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 320/672 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMBP2 | c.2987G>A p.G996E | Missense Mutation (SNP) | VAF 119/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASE10 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 288/579 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- RNF128 | c.523A>C p.K175Q (on ENST00000255499 / NM_194463.2; = p.K149Q on NM_024539.3) | Missense Mutation (SNP) | VAF 152/152 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- RP1 | c.3383C>T p.S1128L | Missense Mutation (SNP) | VAF 96/422 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, varscan2
- RP1L1 | c.2717G>A p.G906E | Missense Mutation (SNP) | VAF 408/836 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- RYR1 | c.6229G>A p.E2077K | Missense Mutation (SNP) | VAF 204/427 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RYR3 | c.7823C>T p.S2608F (on ENST00000389232; = p.S2609F on NM_001036.6) | Missense Mutation (SNP) | VAF 127/294 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- RYR3 | c.9224C>T p.P3075L (on ENST00000389232; = p.P3076L on NM_001036.6) | Missense Mutation (SNP) | VAF 187/413 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SACS | c.10984G>A p.E3662K | Missense Mutation (SNP) | VAF 185/423 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SAMD9 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 206/329 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- SAMSN1 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 160/389 reads (41%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SCAF1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 139/276 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- SETBP1 | c.3943C>T p.Q1315* | Nonsense Mutation (SNP) | VAF 192/416 reads (46%) | called by muse, mutect2, varscan2
- SGIP1 | c.951T>A p.D317E | Missense Mutation (SNP) | VAF 49/454 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SH3TC2 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 288/288 reads (100%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.3782G>A p.G1261E | Missense Mutation (SNP) | VAF 150/330 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- SLC12A5 | c.1220C>T p.P407L (on ENST00000454036 / NM_001134771.2; = p.P384L on NM_020708.5) | Missense Mutation (SNP) | VAF 240/539 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC13A1 | c.1532A>G p.N511S | Missense Mutation (SNP) | VAF 164/460 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SLC25A26 | c.482T>G p.L161* | Nonsense Mutation (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- SLC36A1 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 180/181 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC6A1 | c.1645C>T p.P549S | Missense Mutation (SNP) | VAF 204/439 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC7A6OS | c.550G>C p.G184R | Missense Mutation (SNP) | VAF 205/451 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLIT2 | c.1523A>G p.E508G | Missense Mutation (SNP) | VAF 201/441 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- SMPD3 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 197/388 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SMTNL2 | c.632C>G p.T211S (on ENST00000389313 / NM_001114974.2; = p.T67S on NM_198501.3) | Missense Mutation (SNP) | VAF 274/586 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SNX19 | c.2608C>T p.P870S | Missense Mutation (SNP) | VAF 169/385 reads (44%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- SNX6 | c.599T>A p.F200Y (on ENST00000652385; = p.F72Y on NM_021249.5) | Missense Mutation (SNP) | VAF 126/283 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- SORCS2 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 151/375 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOX10 | c.512A>G p.Y171C | Missense Mutation (SNP) | VAF 339/764 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPON1 | c.2261-1G>A p.X754_splice | Splice Site (SNP) | VAF 149/299 reads (50%) | called by muse, mutect2, varscan2
- SPTAN1 | c.3602C>T p.T1201I | Missense Mutation (SNP) | VAF 191/440 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SRCAP | c.4265C>T p.P1422L | Missense Mutation (SNP) | VAF 239/506 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- SSC5D | c.3712A>G p.T1238A | Missense Mutation (SNP) | VAF 346/825 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYT6 | c.302C>T p.P101L (on ENST00000610222 / NM_001366225.1; = p.P16L on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 304/642 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SYTL4 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 136/136 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- SYVN1 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 147/326 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- TECPR2 | c.2089C>T p.L697F | Missense Mutation (SNP) | VAF 217/495 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- TECRL | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TONSL | c.3751G>C p.A1251P | Missense Mutation (SNP) | VAF 184/607 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- TRAPPC10 | c.1888C>T p.H630Y | Missense Mutation (SNP) | VAF 223/457 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRPS1 | c.172G>A p.E58K (on ENST00000220888 / NM_001330599.2; = p.E71K on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 183/651 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- TTN | c.70136G>A p.R23379K (on ENST00000591111; = p.R15955K on NM_003319.4) | Missense Mutation (SNP) | VAF 223/448 reads (50%) | PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TUBGCP3 | c.1116T>G p.Y372* | Nonsense Mutation (SNP) | VAF 321/649 reads (49%) | called by muse, mutect2, varscan2
- UBR4 | c.2109T>G p.D703E | Missense Mutation (SNP) | VAF 97/227 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- UCP1 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 195/419 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT2A3 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 101/234 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- UNC13C | c.3176C>T p.S1059F | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- UPF2 | c.3075A>C p.E1025D | Missense Mutation (SNP) | VAF 156/341 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- UTY | c.1246T>C p.Y416H | Missense Mutation (SNP) | VAF 177/177 reads (100%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- VGLL3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 135/312 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- VPS13A | c.1669T>G p.S557A | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- WDR87 | c.1894C>G p.L632V | Missense Mutation (SNP) | VAF 15/509 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- XIRP2 | c.548C>T p.P183L (on ENST00000628543; = p.P358L on NM_152381.6) | Missense Mutation (SNP) | VAF 144/357 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC3H11B | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 78/297 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ZNF134 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 233/482 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF253 | c.343G>A p.G115S | Missense Mutation (SNP) | VAF 192/391 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF423 | c.2018C>T p.P673L (on ENST00000563137 / NM_001379286.1; = p.P665L on NM_015069.4) | Missense Mutation (SNP) | VAF 267/580 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- ZNF536 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 424/909 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF536 | c.2312G>A p.R771K | Missense Mutation (SNP) | VAF 155/328 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF547 | c.245C>G p.S82C | Missense Mutation (SNP) | VAF 224/453 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZPBP2 | c.285G>A p.M95I (on ENST00000348931 / NM_199321.3; = p.M73I on NM_198844.3) | Missense Mutation (SNP) | VAF 127/264 reads (48%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ABCC10 | c.1722C>T p.F574= (on ENST00000372530 / NM_001198934.2; = p.F531= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 241/472 reads (51%) | called by muse, mutect2, varscan2
- ABCC8 | c.1581G>A p.R527= | Silent (SNP) | VAF 258/517 reads (50%) | catalogued as rs750360514, CD016052, COSV56856861; called by muse, mutect2, varscan2
- ADCY10 | c.432G>A p.K144= | Silent (SNP) | VAF 127/265 reads (48%) | catalogued as COSV100896878; called by muse, mutect2, varscan2
- AKR1C1 | c.696C>T p.S232= | Silent (SNP) | VAF 211/664 reads (32%) | called by muse, mutect2, varscan2
- ALKBH4 | c.618C>T p.A206= | Silent (SNP) | VAF 372/1031 reads (36%) | catalogued as rs1166582994; called by muse, mutect2, varscan2
- ARHGEF7 | c.1179C>T p.S393= (on ENST00000375741 / NM_001113511.2; = p.S215= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 210/441 reads (48%) | catalogued as COSV54538507; called by muse, mutect2, varscan2
- ASXL3 | c.1329G>A p.L443= | Silent (SNP) | VAF 153/349 reads (44%) | called by muse, mutect2, varscan2
- ATP2B2 | c.861C>T p.T287= | Silent (SNP) | VAF 194/447 reads (43%) | catalogued as rs780890460, COSV59506843; called by muse, mutect2, varscan2
- ATP2B2 | c.330C>T p.I110= | Silent (SNP) | VAF 370/737 reads (50%) | called by muse, mutect2, varscan2
- B4GALNT2 | c.993C>T p.L331= | Silent (SNP) | VAF 134/337 reads (40%) | catalogued as rs745364695, COSV100302348; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 186/438 reads (42%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- BCL3 | c.387C>T p.T129= | Silent (SNP) | VAF 218/462 reads (47%) | called by muse, mutect2, varscan2
- BDP1 | c.3540T>C p.G1180= | Silent (SNP) | VAF 351/652 reads (54%) | called by muse, mutect2
- BRCA2 | c.999C>T p.F333= | Silent (SNP) | VAF 198/431 reads (46%) | called by muse, mutect2, varscan2
- BRCA2 | c.1752A>G p.K584= | Silent (SNP) | VAF 151/360 reads (42%) | called by muse, mutect2, varscan2
- BTNL3 | c.984G>A p.K328= | Silent (SNP) | VAF 337/547 reads (62%) | catalogued as COSV61565448, COSV61566204; called by muse, mutect2, varscan2
- C10orf71 | c.2568G>A p.T856= | Silent (SNP) | VAF 267/267 reads (100%) | catalogued as rs746121240; called by muse, mutect2, varscan2
- C2orf76 | c.39C>T p.I13= | Silent (SNP) | VAF 185/449 reads (41%) | catalogued as COSV58348213; called by muse, mutect2, varscan2
- C3 | c.1896G>A p.G632= | Silent (SNP) | VAF 202/444 reads (45%) | catalogued as COSV55581411; called by muse, mutect2, varscan2
- CA10 | c.84C>T p.I28= | Silent (SNP) | VAF 110/283 reads (39%) | catalogued as COSV53351691; called by muse, mutect2, varscan2
- CA2 | c.777C>T p.F259= | Silent (SNP) | VAF 260/416 reads (63%) | called by muse, mutect2, varscan2
- CACNB2 | c.273C>T p.D91= (on ENST00000324631 / NM_201596.3; = p.D36= on NM_000724.4) | Silent (SNP) | VAF 189/435 reads (43%) | catalogued as rs147650257; called by muse, mutect2, varscan2
- CAMSAP3 | c.2298C>T p.T766= | Silent (SNP) | VAF 499/1041 reads (48%) | catalogued as rs1384336027; called by muse, mutect2, varscan2
- CAPN9 | c.393C>T p.F131= | Silent (SNP) | VAF 170/360 reads (47%) | catalogued as COSV55233720; called by muse, mutect2, varscan2
- CARD11 | c.210C>T p.I70= | Silent (SNP) | VAF 145/317 reads (46%) | called by muse, mutect2, varscan2
- CCDC159 | c.571C>T p.L191= | Silent (SNP) | VAF 166/328 reads (51%) | called by muse, mutect2, varscan2
- CCR8 | c.624G>A p.L208= | Silent (SNP) | VAF 198/428 reads (46%) | called by muse, mutect2, varscan2
- CDH5 | c.345G>A p.E115= | Silent (SNP) | VAF 302/743 reads (41%) | catalogued as rs1211000132; called by muse, mutect2
- CDK6 | c.492C>T p.F164= | Silent (SNP) | VAF 414/690 reads (60%) | catalogued as rs774750394, COSV56005149; called by muse, mutect2, varscan2
- CEACAM19 | c.297C>T p.I99= | Silent (SNP) | VAF 220/485 reads (45%) | catalogued as rs764374932; called by muse, mutect2, varscan2
- CFAP126 | c.384G>A p.K128= | Silent (SNP) | VAF 182/383 reads (48%) | called by muse, mutect2, varscan2
- CFHR1 | c.552G>A p.G184= | Silent (SNP) | VAF 118/118 reads (100%) | catalogued as rs750090708; called by muse, mutect2, varscan2
- CHRM2 | c.501G>A p.G167= | Silent (SNP) | VAF 431/713 reads (60%) | called by muse, mutect2, varscan2
- CHST10 | c.765G>A p.Q255= | Silent (SNP) | VAF 248/540 reads (46%) | called by muse, mutect2, varscan2
- CILP | c.861C>T p.L287= | Silent (SNP) | VAF 192/431 reads (45%) | catalogued as COSV56025958; called by muse, mutect2, varscan2
- CLCN1 | c.327G>A p.V109= | Silent (SNP) | VAF 120/361 reads (33%) | called by muse, mutect2, varscan2
- CLEC4M | c.924T>G p.T308= | Silent (SNP) | VAF 128/249 reads (51%) | called by muse, mutect2, varscan2
- CLIC6 | c.84C>T p.P28= | Silent (SNP) | VAF 408/825 reads (49%) | catalogued as rs1192267571; called by muse, mutect2, varscan2
- CNTNAP5 | c.1083C>T p.S361= | Silent (SNP) | VAF 171/392 reads (44%) | catalogued as rs778725471; called by muse, mutect2, varscan2
- COL26A1 | c.222G>A p.T74= | Silent (SNP) | VAF 477/802 reads (59%) | catalogued as rs373555150; called by muse, mutect2, varscan2
- COL4A4 | c.1980T>C p.G660= | Silent (SNP) | VAF 185/336 reads (55%) | called by muse, varscan2
- CORO1C | c.1209G>A p.K403= | Silent (SNP) | VAF 221/452 reads (49%) | catalogued as rs767688304; called by muse, mutect2, varscan2
- CPLX1 | c.375C>T p.P125= | Silent (SNP) | VAF 182/367 reads (50%) | catalogued as rs770257151; called by muse, mutect2, varscan2
- CTC1 | c.3456C>T p.L1152= | Silent (SNP) | VAF 205/417 reads (49%) | called by muse, mutect2, varscan2
- CYP1A2 | c.678C>T p.F226= | Silent (SNP) | VAF 208/479 reads (43%) | catalogued as COSV59659773; called by muse, mutect2, varscan2
- CYP21A2 | c.171G>C p.G57= | Silent (SNP) | VAF 302/756 reads (40%) | called by muse, varscan2
- CYP2C18 | c.940C>T p.L314= | Silent (SNP) | VAF 174/174 reads (100%) | called by muse, mutect2, varscan2
- DMRT3 | c.1272C>T p.V424= | Silent (SNP) | VAF 204/495 reads (41%) | called by muse, mutect2, varscan2
- DMRTC2 | c.453C>T p.S151= | Silent (SNP) | VAF 190/363 reads (52%) | called by muse, varscan2
- DNAH5 | c.4812C>T p.F1604= | Silent (SNP) | VAF 155/436 reads (36%) | catalogued as COSV54248062, COSV54253190; called by muse, mutect2, varscan2
- DNAH9 | c.10527G>A p.L3509= | Silent (SNP) | VAF 132/292 reads (45%) | called by muse, mutect2, varscan2
- DNMT3B | c.504C>T p.I168= | Silent (SNP) | VAF 304/670 reads (45%) | catalogued as rs781020047; ClinVar: likely benign; called by muse, mutect2, varscan2
- DOCK2 | c.909C>G p.G303= | Silent (SNP) | VAF 133/524 reads (25%) | called by muse, mutect2, varscan2
- DSCAM | c.4689C>T p.F1563= | Silent (SNP) | VAF 161/348 reads (46%) | catalogued as rs201376842, COSV68023011; called by muse, mutect2, varscan2
- DSG1 | c.2691G>A p.R897= | Silent (SNP) | VAF 243/478 reads (51%) | catalogued as COSV99935661; called by muse, mutect2, varscan2
- E2F8 | c.1419C>T p.A473= | Silent (SNP) | VAF 239/517 reads (46%) | called by muse, mutect2, varscan2
- EIF2B2 | c.357C>T p.N119= | Silent (SNP) | VAF 234/498 reads (47%) | called by muse, mutect2, varscan2
- ENDOD1 | c.1293C>T p.V431= | Silent (SNP) | VAF 258/515 reads (50%) | called by muse, mutect2, varscan2
- EPHA2 | c.915C>T p.T305= | Silent (SNP) | VAF 319/659 reads (48%) | called by muse, mutect2, varscan2
- EPN2 | c.615C>T p.C205= | Silent (SNP) | VAF 265/577 reads (46%) | called by muse, varscan2
- EPO | c.441C>T p.S147= | Silent (SNP) | VAF 309/491 reads (63%) | catalogued as COSV53161911; called by muse, mutect2, varscan2
- EVPL | c.2310C>T p.P770= | Silent (SNP) | VAF 355/741 reads (48%) | called by muse, mutect2, varscan2
- FBN3 | c.7947C>T p.V2649= | Silent (SNP) | VAF 161/359 reads (45%) | called by muse, mutect2, varscan2
- FGF23 | c.324C>T p.F108= | Silent (SNP) | VAF 158/333 reads (47%) | catalogued as rs201114020, COSV52975615; called by muse, mutect2, varscan2
- FIGNL2 | c.321C>T p.P107= | Silent (SNP) | VAF 328/719 reads (46%) | called by muse, mutect2, varscan2
- FMO3 | c.273C>T p.I91= | Silent (SNP) | VAF 199/419 reads (47%) | catalogued as COSV100882568, COSV63007970; called by muse, mutect2, varscan2
- FMO3 | c.1122C>T p.S374= | Silent (SNP) | VAF 189/403 reads (47%) | catalogued as rs867914992, COSV63006550; called by muse, mutect2, varscan2
- FSIP2 | c.16434G>A p.K5478= | Silent (SNP) | VAF 169/371 reads (46%) | called by muse, mutect2, varscan2
- FSIP2 | c.19122A>G p.S6374= | Silent (SNP) | VAF 154/385 reads (40%) | called by muse, mutect2, varscan2
- GAREM1 | c.759C>T p.S253= | Silent (SNP) | VAF 244/508 reads (48%) | called by muse, mutect2, varscan2
- GAS7 | c.1266C>T p.H422= (on ENST00000432992 / NM_201433.2; = p.H282= on NM_003644.3) | Silent (SNP) | VAF 217/534 reads (41%) | catalogued as rs1179969708; called by muse, mutect2, varscan2
- GNAO1 | c.411C>T p.I137= | Silent (SNP) | VAF 224/529 reads (42%) | catalogued as COSV52610682; called by muse, mutect2, varscan2
- GPHB5 | c.96C>T p.T32= | Silent (SNP) | VAF 270/569 reads (47%) | called by muse, mutect2, varscan2
- GPR4 | c.969G>A p.L323= | Silent (SNP) | VAF 403/793 reads (51%) | called by muse, mutect2, varscan2
- H1-2 | c.336C>T p.A112= | Silent (SNP) | VAF 256/590 reads (43%) | catalogued as rs142935980; called by muse, varscan2
- H1-3 | c.384G>A p.K128= | Silent (SNP) | VAF 408/707 reads (58%) | catalogued as rs1287446183; called by muse, mutect2, varscan2
- HAO2 | c.198G>A p.G66= | Silent (SNP) | VAF 242/525 reads (46%) | called by muse, mutect2, varscan2
- HCN1 | c.558C>T p.F186= | Silent (SNP) | VAF 216/534 reads (40%) | catalogued as rs1060500097, COSV57495408; called by muse, mutect2, varscan2
- HECW2 | c.1287C>T p.S429= | Silent (SNP) | VAF 154/384 reads (40%) | catalogued as COSV53662765; called by muse, mutect2, varscan2
- HK3 | c.1638G>A p.T546= | Silent (SNP) | VAF 244/709 reads (34%) | catalogued as rs758157580, COSV52844179; called by muse, mutect2, varscan2
- HSF4 | c.387C>T p.G129= | Silent (SNP) | VAF 267/534 reads (50%) | called by muse, mutect2, varscan2
- HYDIN | c.4626C>T p.D1542= | Silent (SNP) | VAF 113/292 reads (39%) | catalogued as rs552617421; called by muse, mutect2, varscan2
- IGLV1-47 | c.138C>T p.S46= | Silent (SNP) | VAF 183/328 reads (56%) | catalogued as rs1206577030; called by muse, mutect2, varscan2
- IGLV3-19 | c.225G>A p.G75= | Silent (SNP) | VAF 169/362 reads (47%) | called by muse, mutect2, varscan2
- IGSF21 | c.729G>A p.T243= | Silent (SNP) | VAF 366/735 reads (50%) | catalogued as rs371864848, COSV52137711; called by muse, mutect2, varscan2
- IKZF4 | c.711C>T p.H237= | Silent (SNP) | VAF 128/295 reads (43%) | called by muse, mutect2, varscan2
- IRF6 | c.1200G>A p.R400= | Silent (SNP) | VAF 148/336 reads (44%) | catalogued as rs780377253, COSV54214666; called by muse, mutect2, varscan2
- ISM2 | c.426G>A p.E142= | Silent (SNP) | VAF 97/241 reads (40%) | catalogued as rs1490667085; called by muse, mutect2, varscan2
- ITGA2B | c.2514C>T p.S838= | Silent (SNP) | VAF 254/547 reads (46%) | called by muse, mutect2, varscan2
- ITGA9 | c.2835G>A p.V945= | Silent (SNP) | VAF 181/441 reads (41%) | called by muse, mutect2, varscan2
- KCNB1 | c.1335C>T p.I445= | Silent (SNP) | VAF 211/455 reads (46%) | catalogued as rs368667514, COSV65569351; called by muse, mutect2, varscan2
- KCNH5 | c.2013G>A p.R671= | Silent (SNP) | VAF 96/208 reads (46%) | catalogued as COSV59770839; called by muse, mutect2, varscan2
- KCTD2 | c.84C>T p.V28= | Silent (SNP) | VAF 315/667 reads (47%) | catalogued as rs958143696; called by muse, mutect2, varscan2
- KIF1A | c.4491C>T p.L1497= (on ENST00000320389 / NM_001379639.1; = p.L1489= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 222/405 reads (55%) | catalogued as rs779877210; called by muse, mutect2, varscan2
- KIF21B | c.2607C>T p.I869= | Silent (SNP) | VAF 251/537 reads (47%) | catalogued as rs746319254, COSV59751690; called by muse, mutect2, varscan2
- KIRREL3 | c.336G>A p.L112= | Silent (SNP) | VAF 298/598 reads (50%) | called by muse, mutect2, varscan2
- KLHDC7A | c.6C>T p.F2= | Silent (SNP) | VAF 133/273 reads (49%) | catalogued as rs1227974701; called by muse, mutect2, varscan2
- KLHL28 | c.1590C>T p.V530= | Silent (SNP) | VAF 176/358 reads (49%) | catalogued as rs759182642; called by muse, varscan2
- KLK13 | c.693C>T p.I231= | Silent (SNP) | VAF 186/429 reads (43%) | catalogued as rs765329818; called by muse, mutect2, varscan2
- KRT76 | c.516C>T p.I172= | Silent (SNP) | VAF 171/384 reads (45%) | catalogued as rs146014128, COSV60121833; called by muse, mutect2, varscan2
- KRT82 | c.1245C>T p.I415= | Silent (SNP) | VAF 155/390 reads (40%) | catalogued as rs149421540; called by muse, mutect2, varscan2
- KRTAP1-5 | c.48C>T p.I16= | Silent (SNP) | VAF 168/351 reads (48%) | called by muse, mutect2, varscan2
- KRTAP5-1 | c.339G>A p.G113= | Silent (SNP) | VAF 140/250 reads (56%) | called by mutect2, varscan2
- LAMP5 | c.99G>A p.V33= | Silent (SNP) | VAF 188/382 reads (49%) | called by muse, mutect2, varscan2
- LDB2 | c.771G>A p.R257= | Silent (SNP) | VAF 201/455 reads (44%) | catalogued as rs539193176; called by muse, mutect2, varscan2
- LEMD1 | c.543T>C p.G181= | Silent (SNP) | VAF 133/296 reads (45%) | catalogued as COSV100903452; called by muse, mutect2, varscan2
- LRFN2 | c.141C>T p.P47= | Silent (SNP) | VAF 324/602 reads (54%) | called by muse, mutect2, varscan2
- MAGEA6 | c.750C>T p.F250= | Silent (SNP) | VAF 212/212 reads (100%) | catalogued as rs782585932, COSV61448617, COSV61449289; called by muse, mutect2, varscan2
- MALRD1 | c.978C>T p.F326= | Silent (SNP) | VAF 176/373 reads (47%) | called by muse, mutect2, varscan2
- MALRD1 | c.1371G>A p.Q457= | Silent (SNP) | VAF 181/393 reads (46%) | called by muse, mutect2, varscan2
- MCF2L2 | c.1389C>T p.I463= | Silent (SNP) | VAF 196/433 reads (45%) | catalogued as rs923350801; called by muse, mutect2, varscan2
- MED16 | c.2337C>T p.I779= | Silent (SNP) | VAF 329/698 reads (47%) | catalogued as rs139834365; called by muse, mutect2, varscan2
- MEIS3 | c.975C>T p.I325= (on ENST00000558555 / NM_001346148.1; = p.I371= on NM_020160.3) | Silent (SNP) | VAF 198/427 reads (46%) | catalogued as rs1223053853, COSV58983224; called by muse, mutect2, varscan2
- MEP1A | c.1977C>T p.G659= | Silent (SNP) | VAF 343/672 reads (51%) | catalogued as COSV57920679; called by muse, mutect2, varscan2
- MGAM | c.5487C>T p.P1829= | Silent (SNP) | VAF 290/505 reads (57%) | catalogued as COSV72074007; called by muse, mutect2, varscan2
- MROH2B | c.3345G>A p.G1115= | Silent (SNP) | VAF 241/415 reads (58%) | catalogued as rs549275471, COSV68182646; called by muse, mutect2, varscan2
- MTUS2 | c.936G>A p.L312= | Silent (SNP) | VAF 253/548 reads (46%) | called by muse, varscan2
- MUC4 | c.15942C>T p.P5314= (on ENST00000463781 / NM_018406.7; = p.P1078= on NM_004532.6) | Silent (SNP) | VAF 457/2051 reads (22%) | catalogued as rs1367696878, COSV100204530, COSV57797019; called by muse, mutect2
- MXRA5 | c.2331G>A p.Q777= | Silent (SNP) | VAF 317/317 reads (100%) | catalogued as COSV54243153; called by muse, mutect2, varscan2
- MYO15A | c.624C>T p.F208= | Silent (SNP) | VAF 339/641 reads (53%) | catalogued as COSV52751465; called by muse, mutect2, varscan2
- MYO5C | c.340T>C p.L114= | Silent (SNP) | VAF 194/386 reads (50%) | called by muse, mutect2, varscan2
- MYOCD | c.387G>A p.V129= | Silent (SNP) | VAF 164/355 reads (46%) | catalogued as COSV58513519; called by muse, mutect2, varscan2
- MYOCD | c.2382C>T p.I794= | Silent (SNP) | VAF 304/600 reads (51%) | catalogued as COSV100591551, COSV58509984; called by muse, mutect2, varscan2
- NCR3LG1 | c.702C>T p.S234= | Silent (SNP) | VAF 186/413 reads (45%) | called by muse, mutect2, varscan2
- NLGN4Y | c.2100G>A p.K700= | Silent (SNP) | VAF 257/257 reads (100%) | called by muse, mutect2, varscan2
- NLRP2 | c.1737G>A p.P579= | Silent (SNP) | VAF 287/640 reads (45%) | catalogued as rs530937104; called by muse, mutect2, varscan2
- NLRP2 | c.1887C>T p.S629= | Silent (SNP) | VAF 308/683 reads (45%) | called by muse, mutect2, varscan2
- NPIPB5 | c.1098C>T p.L366= | Silent (SNP) | VAF 157/612 reads (26%) | called by muse, mutect2, varscan2
- NPTX2 | c.864C>T p.P288= | Silent (SNP) | VAF 200/542 reads (37%) | catalogued as rs1464132127, COSV55718458; called by muse, mutect2, varscan2
- NTRK3 | c.2481G>A p.L827= (on ENST00000360948 / NM_001012338.2; = p.L813= on NM_002530.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 298/614 reads (49%) | catalogued as COSV62308482, COSV62312574, COSV62316524; called by muse, mutect2, varscan2
- NXPH3 | c.183C>T p.A61= | Silent (SNP) | VAF 456/908 reads (50%) | catalogued as rs778437274; called by muse, mutect2, varscan2
- OGDH | c.2124C>T p.P708= | Silent (SNP) | VAF 206/476 reads (43%) | called by muse, mutect2, varscan2
- OR10G6 | c.402C>T p.F134= | Silent (SNP) | VAF 222/436 reads (51%) | catalogued as rs1332757912; called by muse, mutect2, varscan2
- OR1C1 | c.504C>T p.F168= | Silent (SNP) | VAF 203/461 reads (44%) | catalogued as COSV101376256; called by muse, mutect2, varscan2
- OR1G1 | c.738C>T p.S246= | Silent (SNP) | VAF 228/449 reads (51%) | catalogued as rs762912158, COSV61030515; called by muse, mutect2, varscan2
- OR1L3 | c.462C>T p.F154= | Silent (SNP) | VAF 185/389 reads (48%) | catalogued as rs750460042; called by muse, mutect2, varscan2
- OR2AG2 | c.618C>T p.F206= | Silent (SNP) | VAF 242/470 reads (51%) | called by muse, mutect2, varscan2
- OR2G6 | c.237A>C p.P79= | Silent (SNP) | VAF 290/565 reads (51%) | called by muse, mutect2, varscan2
- OR2L5 | c.804A>T p.T268= | Silent (SNP) | VAF 110/263 reads (42%) | called by muse, mutect2, varscan2
- OR51D1 | c.18C>T p.L6= | Silent (SNP) | VAF 158/355 reads (45%) | called by muse, mutect2, varscan2
- OR51I1 | c.423C>T p.N141= | Silent (SNP) | VAF 220/518 reads (42%) | called by muse, mutect2, varscan2
- OR5B12 | c.675G>A p.K225= | Silent (SNP) | VAF 153/342 reads (45%) | catalogued as COSV56906534; called by muse, varscan2
- OR5BS1P | c.855C>T p.P285= | Silent (SNP) | VAF 196/442 reads (44%) | called by muse, varscan2
- OR5D18 | c.939C>T p.Y313= | Silent (SNP) | VAF 89/181 reads (49%) | called by muse, mutect2, varscan2
- OR8H2 | c.765G>A p.L255= | Silent (SNP) | VAF 57/143 reads (40%) | catalogued as rs1364453583, COSV57943487; called by muse, mutect2, varscan2
- OTOF | c.5982C>T p.I1994= (on ENST00000272371 / NM_194248.3; = p.I1227= on NM_004802.4) | Silent (SNP) | VAF 231/711 reads (32%) | catalogued as COSV55502185; called by muse, mutect2, varscan2
- P2RY6 | c.72C>T p.F24= | Silent (SNP) | VAF 300/649 reads (46%) | called by muse, mutect2, varscan2
- PAPPA2 | c.1725C>T p.S575= | Silent (SNP) | VAF 270/583 reads (46%) | catalogued as rs959030331, COSV62786896; called by muse, mutect2, varscan2
- PAX7 | c.114C>T p.V38= | Silent (SNP) | VAF 258/568 reads (45%) | called by muse, mutect2
- PCDHA11 | c.685T>C p.L229= | Silent (SNP) | VAF 256/258 reads (99%) | catalogued as rs782425741; called by muse, mutect2, varscan2
- PCDHA13 | c.270C>T p.I90= | Silent (SNP) | VAF 545/547 reads (100%) | catalogued as rs782086663, COSV56477733; called by muse, varscan2
- PCDHA9 | c.1125C>T p.I375= | Silent (SNP) | VAF 421/424 reads (99%) | catalogued as COSV65332115; called by muse, mutect2, varscan2
- PCDHGA10 | c.1755C>T p.S585= | Silent (SNP) | VAF 630/632 reads (100%) | catalogued as rs561548499; called by muse, mutect2, varscan2
- PCF11 | c.3411T>C p.D1137= | Silent (SNP) | VAF 168/365 reads (46%) | called by muse, mutect2, varscan2
- PCSK1 | c.1824G>A p.T608= | Silent (SNP) | VAF 277/479 reads (58%) | catalogued as rs753294559; called by muse, mutect2, varscan2
- PDK2 | c.468C>T p.D156= | Silent (SNP) | VAF 234/493 reads (47%) | called by muse, mutect2, varscan2
- PER3 | c.1845C>T p.I615= | Silent (SNP) | VAF 286/574 reads (50%) | called by muse, mutect2, varscan2
- PHF21B | c.1395G>A p.K465= | Silent (SNP) | VAF 233/496 reads (47%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3687G>A p.R1229= | Silent (SNP) | VAF 94/456 reads (21%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.7671G>A p.V2557= | Silent (SNP) | VAF 402/635 reads (63%) | called by muse, mutect2, varscan2
- PLA2G4D | c.2208C>T p.S736= | Silent (SNP) | VAF 202/487 reads (41%) | called by muse, mutect2, varscan2
- PLIN1 | c.1500C>T p.F500= | Silent (SNP) | VAF 359/754 reads (48%) | catalogued as rs1376154735; called by muse, varscan2
- POSTN | c.372G>A p.E124= | Silent (SNP) | VAF 217/439 reads (49%) | catalogued as rs369828402, COSV65712010; called by muse, mutect2, varscan2
- PPP4R3C | c.1011C>T p.F337= | Silent (SNP) | VAF 102/104 reads (98%) | called by mutect2, varscan2
- PRAMEF4 | c.1161C>T p.F387= | Silent (SNP) | VAF 170/181 reads (94%) | catalogued as COSV52441102; called by muse, mutect2
- PROZ | c.186C>T p.I62= | Silent (SNP) | VAF 163/398 reads (41%) | catalogued as COSV61439869; called by muse, mutect2, varscan2
- PRR14 | c.651A>G p.P217= | Silent (SNP) | VAF 147/344 reads (43%) | called by muse, mutect2, varscan2
- PTCHD1 | c.1155C>T p.T385= | Silent (SNP) | VAF 18/372 reads (5%) | catalogued as COSV101037429; called by muse, mutect2
- PXDN | c.2586C>T p.I862= | Silent (SNP) | VAF 287/538 reads (53%) | catalogued as rs1189597990, COSV53229472; called by muse, mutect2, varscan2
- PXDN | c.1278C>T p.F426= | Silent (SNP) | VAF 146/269 reads (54%) | catalogued as rs753957482; called by muse, mutect2, varscan2
- RAD54L | c.1089G>A p.K363= | Silent (SNP) | VAF 219/446 reads (49%) | called by muse, mutect2, varscan2
- RAG1 | c.99C>T p.F33= | Silent (SNP) | VAF 193/406 reads (48%) | catalogued as COSV55027376; called by muse, mutect2, varscan2
- RANBP17 | c.675C>T p.C225= | Silent (SNP) | VAF 366/634 reads (58%) | catalogued as COSV66652761; called by muse, mutect2, varscan2
- RANBP9 | c.1686C>T p.D562= | Silent (SNP) | VAF 129/443 reads (29%) | catalogued as rs1166044895; called by muse, mutect2, varscan2
- RBBP8NL | c.1794G>A p.E598= | Silent (SNP) | VAF 208/467 reads (45%) | catalogued as rs1188259914; called by mutect2, varscan2
- RELN | c.5802G>A p.K1934= | Silent (SNP) | VAF 118/299 reads (39%) | catalogued as COSV100634488; called by muse, mutect2, varscan2
- RGL1 | c.1314C>T p.I438= (on ENST00000360851 / NM_001297672.2; = p.I473= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 164/354 reads (46%) | catalogued as rs770302492; called by muse, mutect2, varscan2
- RIMBP2 | c.2544C>T p.L848= | Silent (SNP) | VAF 228/493 reads (46%) | catalogued as COSV99898431; called by muse, mutect2, varscan2
- ROR1 | c.297C>T p.V99= | Silent (SNP) | VAF 268/535 reads (50%) | catalogued as rs1464485331; called by muse, mutect2, varscan2
- RP1 | c.3111C>T p.L1037= | Silent (SNP) | VAF 311/541 reads (57%) | called by muse, mutect2, varscan2
- RREB1 | c.126C>T p.S42= | Silent (SNP) | VAF 211/790 reads (27%) | called by muse, mutect2, varscan2
- RYR3 | c.6831C>T p.I2277= (on ENST00000389232; = p.I2278= on NM_001036.6) | Silent (SNP) | VAF 165/436 reads (38%) | catalogued as rs772909257; called by muse, mutect2
- SALL3 | c.2334C>T p.A778= | Silent (SNP) | VAF 409/860 reads (48%) | called by muse, varscan2
- SALL3 | c.3273G>A p.Q1091= | Silent (SNP) | VAF 532/1071 reads (50%) | called by muse, mutect2, varscan2
- SCAF1 | c.3486C>T p.S1162= | Silent (SNP) | VAF 322/694 reads (46%) | catalogued as rs1460100116; called by muse, mutect2, varscan2
- SDHC | c.438C>T p.P146= | Silent (SNP) | VAF 165/407 reads (41%) | catalogued as rs1418513098, COSV100713625; called by muse, mutect2, varscan2
- SERBP1 | c.54C>T p.D18= | Silent (SNP) | VAF 166/376 reads (44%) | called by muse, mutect2, varscan2
- SIPA1L1 | c.2349C>T p.F783= | Silent (SNP) | VAF 212/401 reads (53%) | catalogued as COSV62168385; called by muse, mutect2, varscan2
- SLC12A5 | c.336G>A p.K112= (on ENST00000454036 / NM_001134771.2; = p.K89= on NM_020708.5) | Silent (SNP) | VAF 107/263 reads (41%) | catalogued as rs762781492; called by muse, mutect2, varscan2
- SLC1A3 | c.1599G>A p.E533= | Silent (SNP) | VAF 159/465 reads (34%) | called by muse, mutect2, varscan2
- SLC22A15 | c.675G>A p.R225= | Silent (SNP) | VAF 119/272 reads (44%) | catalogued as rs1176032648; called by muse, mutect2, varscan2
- SLC26A8 | c.2274T>A p.I758= | Silent (SNP) | VAF 186/357 reads (52%) | called by muse, mutect2, varscan2
- SLC2A9 | c.1401C>T p.L467= | Silent (SNP) | VAF 180/369 reads (49%) | catalogued as rs755915063; called by muse, mutect2, varscan2
- SLC35F3 | c.267G>A p.L89= (on ENST00000366617 / NM_001300845.1; = p.L158= on NM_173508.4) | Silent (SNP) | VAF 339/749 reads (45%) | called by muse, mutect2, varscan2
- SLC6A3 | c.153G>A p.R51= | Silent (SNP) | VAF 699/1126 reads (62%) | called by muse, mutect2, varscan2
- SLC7A14 | c.726G>A p.A242= | Silent (SNP) | VAF 186/385 reads (48%) | catalogued as rs752901596, COSV51580118; called by muse, mutect2, varscan2
- SLC9A4 | c.2022G>A p.R674= | Silent (SNP) | VAF 118/244 reads (48%) | called by muse, varscan2
- SLIT3 | c.2256G>A p.K752= | Silent (SNP) | VAF 394/619 reads (64%) | called by muse, mutect2, varscan2
- SORL1 | c.6027G>A p.G2009= | Silent (SNP) | VAF 176/380 reads (46%) | catalogued as rs867962008; called by muse, mutect2, varscan2
- SPINK5 | c.969G>A p.G323= | Silent (SNP) | VAF 239/239 reads (100%) | called by muse, mutect2, varscan2
- SPOCD1 | c.6C>T p.S2= | Silent (SNP) | VAF 133/290 reads (46%) | called by muse, mutect2, varscan2
- SSX7 | c.27G>A p.R9= | Silent (SNP) | VAF 110/110 reads (100%) | called by muse, mutect2, varscan2
- STARD13 | c.1173G>A p.E391= (on ENST00000336934 / NM_001243476.3; = p.E273= on NM_052851.3) | Silent (SNP) | VAF 190/400 reads (48%) | catalogued as COSV55228215; called by muse, mutect2, varscan2
- STRA8 | c.675G>A p.K225= (on ENST00000275764; = p.K203= on NM_182489.2) | Silent (SNP) | VAF 630/1070 reads (59%) | called by muse, mutect2, varscan2
- TET1 | c.987C>T p.F329= | Silent (SNP) | VAF 236/237 reads (100%) | catalogued as rs531819620; called by muse, mutect2, varscan2
- TEX15 | c.2826G>A p.G942= (on ENST00000256246; = p.G1325= on NM_001350162.2) | Silent (SNP) | VAF 162/362 reads (45%) | called by muse, mutect2, varscan2
- TEX51 | c.12C>T p.L4= | Silent (SNP) | VAF 144/301 reads (48%) | called by muse, varscan2
- TFAP2C | c.519G>A p.Q173= | Silent (SNP) | VAF 224/490 reads (46%) | called by muse, mutect2, varscan2
- TH | c.177C>T p.T59= | Silent (SNP) | VAF 205/440 reads (47%) | called by muse, mutect2, varscan2
- TIAM1 | c.2862C>T p.P954= | Silent (SNP) | VAF 264/593 reads (45%) | called by muse, mutect2, varscan2
- TLCD4 | c.558C>T p.I186= | Silent (SNP) | VAF 194/451 reads (43%) | catalogued as rs779868562; called by muse, mutect2, varscan2
- TLN2 | c.4263C>T p.L1421= | Silent (SNP) | VAF 198/427 reads (46%) | catalogued as rs1290984348; called by muse, mutect2, varscan2
- TLX3 | c.168C>T p.Y56= | Silent (SNP) | VAF 400/1269 reads (32%) | catalogued as COSV99740642; called by muse, mutect2, varscan2
- TMEM119 | c.789C>T p.A263= | Silent (SNP) | VAF 297/622 reads (48%) | called by muse, mutect2, varscan2
- TNR | c.1326C>T p.F442= | Silent (SNP) | VAF 139/302 reads (46%) | catalogued as rs1418434452, COSV54878703; called by muse, mutect2, varscan2
- TNXB | c.5682G>A p.G1894= (on ENST00000647633; = p.G1647= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 244/454 reads (54%) | called by muse, mutect2, varscan2
- TOX2 | c.846C>T p.F282= (on ENST00000358131 / NM_001098798.2; = p.F231= on NM_032883.3) | Silent (SNP) | VAF 211/398 reads (53%) | catalogued as rs147266413; called by muse, mutect2, varscan2
- TRAV12-3 | c.72G>A p.K24= | Silent (SNP) | VAF 123/269 reads (46%) | called by muse, mutect2, varscan2
- TRIM29 | c.36G>A p.S12= | Silent (SNP) | VAF 326/720 reads (45%) | catalogued as rs779527495; called by muse, mutect2, varscan2
- TRIM68 | c.892C>T p.L298= | Silent (SNP) | VAF 157/330 reads (48%) | called by muse, mutect2, varscan2
- TSHZ2 | c.2091C>T p.A697= | Silent (SNP) | VAF 353/765 reads (46%) | catalogued as COSV61592005; called by muse, mutect2, varscan2
- TTLL1 | c.1194C>T p.S398= | Silent (SNP) | VAF 224/488 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.50607G>A p.R16869= (on ENST00000591111; = p.R9445= on NM_003319.4) | Silent (SNP) | VAF 200/427 reads (47%) | called by muse, mutect2, varscan2
- UBASH3A | c.1857C>T p.S619= | Silent (SNP) | VAF 134/289 reads (46%) | called by muse, mutect2, varscan2
- UBL3 | c.270C>T p.A90= | Silent (SNP) | VAF 185/391 reads (47%) | called by muse, mutect2, varscan2
- USP42 | c.3324G>A p.E1108= | Silent (SNP) | VAF 431/896 reads (48%) | catalogued as rs904387731; called by muse, mutect2, varscan2
- VN1R2 | c.852C>T p.I284= | Silent (SNP) | VAF 212/444 reads (48%) | catalogued as rs988507744; called by muse, mutect2, varscan2
- WDR90 | c.1215C>T p.F405= | Silent (SNP) | VAF 293/623 reads (47%) | catalogued as rs1244104261; called by muse, mutect2, varscan2
- WT1 | c.1347C>T p.S449= | Silent (SNP) | VAF 228/564 reads (40%) | called by muse, mutect2, varscan2
- WWC2 | c.9G>A p.R3= | Silent (SNP) | VAF 196/404 reads (49%) | called by muse, mutect2, varscan2
- ZBTB11 | c.666A>C p.G222= | Silent (SNP) | VAF 245/507 reads (48%) | called by muse, mutect2, varscan2
- ZCCHC13 | c.138C>T p.T46= | Silent (SNP) | VAF 361/361 reads (100%) | called by muse, mutect2, varscan2
- ZKSCAN2 | c.1038G>A p.E346= | Silent (SNP) | VAF 259/511 reads (51%) | called by muse, mutect2, varscan2
- ZNF433 | c.1308C>T p.L436= | Silent (SNP) | VAF 218/417 reads (52%) | called by muse, mutect2, varscan2
- ZNF534 | c.1548C>T p.F516= (on ENST00000332323 / NM_001143939.3; = p.F503= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 186/441 reads (42%) | catalogued as rs766287174; called by muse, mutect2, varscan2
- ZNF831 | c.1455C>T p.F485= | Silent (SNP) | VAF 358/728 reads (49%) | catalogued as rs1207499907; called by muse, mutect2, varscan2
- ZNF841 | c.1974C>T p.F658= (on ENST00000426391 / NM_001369830.1; = p.F774= on NM_001136499.1 and 6 other RefSeq transcripts) | Silent (SNP) | VAF 223/468 reads (48%) | called by muse, mutect2, varscan2
- ZNFX1 | c.1626T>C p.H542= | Silent (SNP) | VAF 185/367 reads (50%) | catalogued as rs754467723; called by muse, mutect2, varscan2
- ZP2 | c.1488C>T p.I496= | Silent (SNP) | VAF 140/278 reads (50%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1046+2967G>A | Intron (SNP) | VAF 169/371 reads (46%) | catalogued as rs1298916301; called by muse, mutect2, varscan2
- AGAP14P | n.1487C>T | RNA (SNP) | VAF 356/744 reads (48%) | called by muse, mutect2, varscan2
- BEAN1 | c.*291C>T | 3'UTR (SNP) | VAF 41/678 reads (6%) | catalogued as rs142124311; called by muse, mutect2
- CD81 | c.67-4328C>T | Intron (SNP) | VAF 259/529 reads (49%) | catalogued as rs1012311551; called by muse, mutect2, varscan2
- DEUP1 | c.790-1790A>C | Intron (SNP) | VAF 73/209 reads (35%) | called by muse, mutect2, varscan2
- EBLN3P | chr9:37079907 G>A | 5'Flank (SNP) | VAF 186/395 reads (47%) | catalogued as rs748429462; called by muse, mutect2, varscan2
- EEF1A1P17 | n.1209G>A | RNA (SNP) | VAF 140/276 reads (51%) | called by muse, mutect2, varscan2
- GLIS1 | chr1:53737825 C>T | 5'Flank (SNP) | VAF 299/628 reads (48%) | called by muse, mutect2, varscan2
- IKZF2 | c.139+18G>A | Intron (SNP) | VAF 166/438 reads (38%) | called by muse, varscan2
- KCNQ1 | c.1393+27955C>T | Intron (SNP) | VAF 79/164 reads (48%) | called by muse, mutect2, varscan2
- LINC00968 | n.297C>A | RNA (SNP) | VAF 129/510 reads (25%) | called by muse, mutect2, varscan2
- LINC00968 | n.296C>T | RNA (SNP) | VAF 130/516 reads (25%) | called by muse, mutect2, varscan2
- MYO7A | c.3503+18G>A | Intron (SNP) | VAF 202/429 reads (47%) | called by muse, mutect2, varscan2
- NDEL1 | c.*184C>A | 3'UTR (SNP) | VAF 220/505 reads (44%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+5021C>T | Intron (SNP) | VAF 291/291 reads (100%) | catalogued as rs747967264, COSV52827594, COSV99475197; called by muse, mutect2, varscan2
- OSTF1P1 | n.469C>T | RNA (SNP) | VAF 189/421 reads (45%) | called by muse, mutect2, varscan2
- PARP8 | c.147-5399C>T | Intron (SNP) | VAF 204/370 reads (55%) | catalogued as rs963756041; called by muse, mutect2, varscan2
- PLCH2 | c.2959+375C>T | Intron (SNP) | VAF 479/993 reads (48%) | catalogued as rs1444959667; called by muse, mutect2, varscan2
- RAB3IL1 | chr11:61920136 G>A | 5'Flank (SNP) | VAF 271/582 reads (47%) | called by muse, mutect2, varscan2
- RASGRP3 | c.-1C>T | 5'UTR (SNP) | VAF 189/189 reads (100%) | catalogued as rs756957301; called by muse, mutect2, varscan2
9 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 9 other) are not listed here.
